Somatic mutation profile of tumor specimen TCGA-BR-8296-01A (aliquot TCGA-BR-8296-01A-11D-2340-08) from TCGA case TCGA-BR-8296, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.9 years (21,527 days).
Specimen TCGA-BR-8296-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8a59ed0-9143-4916-bcb4-403e26b3cfda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8296-10A (Blood Derived Normal), aliquot TCGA-BR-8296-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fd7efdb-58b4-48f1-a9d6-e778aec3c0b6

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 18, Nonsense Mutation 3, Intron 1, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGMO | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV61105557; called by muse, mutect2, varscan2
- CAPN6 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 62/555 reads (11%) | catalogued as rs1420988453, COSV60693798; called by muse, mutect2, varscan2
- CDH20 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV53004433; called by muse, mutect2
- CFHR1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as COSV100258899, COSV57627624; called by mutect2, varscan2
- CLDN25 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs368118465, COSV71620407; called by muse, mutect2, varscan2
- CTNND2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490647469, COSV58864690; called by muse, mutect2, varscan2
- DLL1 | c.1968C>A p.D656E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64536703, COSV64537116; called by muse, mutect2, varscan2
- ECT2 | c.1331C>T p.T444I (on ENST00000392692 / NM_001349098.2; = p.T413I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV51686362; called by muse, mutect2, varscan2
- EPHB1 | c.2218T>C p.Y740H | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67653882; called by muse, mutect2, varscan2
- FAM162B | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV63920036; called by muse, mutect2, varscan2
- FRMD6 | c.1159G>A p.A387T (on ENST00000344768 / NM_001267046.2; = p.A379T on NM_152330.4) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs928666142; called by muse, mutect2
- FSIP2 | c.18300G>C p.E6100D | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV100555652; called by muse, mutect2
- GAD2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as rs1259318388, COSV52150482; called by muse, mutect2, varscan2
- GAS2L3 | c.1342C>G p.P448A | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV57156019; called by muse, mutect2, varscan2
- GAS2L3 | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV57156029; called by muse, mutect2, varscan2
- GAS2L3 | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV57156036; called by muse, mutect2
- HUWE1 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53334525; called by muse, mutect2, varscan2
- L3MBTL3 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs774664869, COSV62387523; called by muse, mutect2
- LILRB5 | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60254414; called by muse, mutect2, varscan2
- MBD4 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51443891; called by muse, mutect2, varscan2
- MRGPRX4 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as rs767806276, COSV58589771; called by muse, mutect2, varscan2
- MTMR1 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64892203; called by muse, mutect2
- MTUS1 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV50550697; called by muse, mutect2, varscan2
- MYH1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779814264, COSV56843571, COSV56851315; called by mutect2, varscan2
- NTN4 | c.1301G>C p.C434S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV59217062; called by muse, mutect2
- PCDH10 | c.2083G>C p.G695R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.094); catalogued as COSV52087484, COSV99993603; called by muse, mutect2, varscan2
- POLG2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs781922249, COSV73346980; called by muse, mutect2, varscan2
- PREX2 | c.2464G>A p.V822M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs190776975, COSV55750393; called by muse, mutect2, varscan2
- PSD4 | c.1217G>A p.W406* | Nonsense Mutation (SNP) | VAF 10/150 reads (7%) | catalogued as COSV55524440; called by muse, mutect2
- RAB10 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV53088173; called by muse, mutect2, varscan2
- RASA3 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV61863540; called by muse, mutect2
- RDH8 | c.868G>A p.V290M (on ENST00000651512; = p.V270M on NM_015725.4) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs768558441, COSV50673907; called by muse, mutect2, varscan2
- RIN1 | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757397798, COSV60925325; called by muse, mutect2, varscan2
- RRP12 | c.1320+1G>C p.X440_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV59664733; called by muse, mutect2, varscan2
- SEMA3A | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54861564; called by muse, mutect2, varscan2
- SETBP1 | c.3180G>A p.M1060I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.31); catalogued as COSV56312797; called by muse, mutect2, varscan2
- SLITRK2 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV59423016; called by muse, mutect2, varscan2
- STAG2 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV54350719; called by muse, mutect2
- TLR5 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.643); catalogued as COSV104415978, COSV60557869; called by muse, mutect2, varscan2
- TOM1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771648997, COSV65897324; called by muse, mutect2, varscan2
- TRMT10A | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV56744435; called by muse, mutect2, varscan2
- TTYH1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050294464, COSV56609639; called by muse, mutect2
- USP51 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1014756592, COSV72351456, COSV72352000; called by muse, mutect2, varscan2
- CEP55 | c.569A>C p.Q190P | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESF1 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.172); called by muse, mutect2
- MSANTD4 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2
- ABCA13 | c.13908G>C p.L4636= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV68943259; called by muse, mutect2
- ABCC1 | c.642C>A p.S214= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60680170, COSV60684419; called by muse, mutect2, varscan2
- APOH | c.729G>A p.P243= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as rs777337011, COSV52771312; called by muse, mutect2, varscan2
- C12orf50 | c.547T>C p.L183= | Silent (SNP) | VAF 5/111 reads (5%) | called by muse, mutect2
- CLDN11 | c.582G>A p.A194= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs369096350; called by muse, mutect2, varscan2
- F2R | c.399C>T p.V133= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV59928276; called by muse, mutect2, varscan2
- GPC5 | c.312G>A p.A104= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs942126306, COSV65576374; called by muse, mutect2, varscan2
- HCAR2 | c.516C>T p.G172= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs202036334, COSV61024240; called by muse, mutect2, varscan2
- MCHR2 | c.651T>C p.Y217= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV55999468; called by muse, mutect2, varscan2
- MTR | c.2325C>T p.I775= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs376941088, COSV63963853; called by muse, mutect2, varscan2
- NLRP12 | c.882C>T p.D294= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs147080557, CM1111600; called by muse, mutect2, varscan2
- PLB1 | c.1860G>A p.R620= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs1230251661, COSV59819209; called by muse, mutect2, varscan2
- PTCHD3 | c.1488T>A p.T496= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV71256280; called by muse, mutect2
- SH2B2 | c.1545C>T p.N515= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs371577042; called by muse, mutect2
- SLC2A6 | c.537C>T p.F179= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs782152058, COSV64141773; called by muse, mutect2, varscan2
- TTC4 | c.420G>A p.V140= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV64884348; called by mutect2, varscan2
- TTI1 | c.2727G>A p.Q909= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100989695, COSV65060407; called by muse, mutect2
- ZHX3 | c.423C>T p.N141= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as rs113667928; called by muse, mutect2, varscan2
- MIR892A | n.43G>A | RNA (SNP) | VAF 24/201 reads (12%) | catalogued as rs1431127386; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442622 C>G | 3'Flank (SNP) | VAF 7/46 reads (15%) | catalogued as COSV62631491; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2064A>T | Intron (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100678666; called by muse, mutect2, varscan2
